Somatic mutation profile of tumor specimen TCGA-CR-5247-01A (aliquot TCGA-CR-5247-01A-01D-2012-08) from TCGA case TCGA-CR-5247, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tonsil, NOS; Tumor grade: G2; Age at diagnosis: 48.8 years (17,810 days).
Specimen TCGA-CR-5247-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9681ddea-aa1f-4c30-b9a7-0e063531f6cf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CR-5247-10A (Blood Derived Normal), aliquot TCGA-CR-5247-10A-01D-2013-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c2501661-4543-4e4b-8d59-9e0a579d8d74

The open-access MAF lists 74 somatic variants for this specimen: 55 protein-altering or splice-affecting, 17 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 17, In Frame Del 2, Splice Site 2, Nonsense Mutation 2, Intron 2, Frame Shift Ins 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASXL1 | c.1934del p.G645Vfs*58 | Frame Shift Del (DEL) | VAF 5/19 reads (26%) | hotspot (GDC flag); catalogued as rs750318549; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- CDKN2A | c.172C>T p.R58* | Nonsense Mutation (SNP) | VAF 10/16 reads (63%) | hotspot (GDC flag); catalogued as rs121913387, CM940227, COSV58682666, COSV58721549, COSV99053472; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- NSD1 | c.5990A>G p.Y1997C | Missense Mutation (SNP) | VAF 53/77 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs797045825, CM052319, CM052320, COSV100729066; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAMTSL1 | c.3523C>A p.Q1175K | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.93); PolyPhen benign (0.444); catalogued as COSV101001814; called by muse, mutect2, varscan2
- AHR | c.2505A>T p.E835D | Missense Mutation (SNP) | VAF 84/176 reads (48%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.13); catalogued as rs146912085; called by muse, mutect2, varscan2
- ARHGAP36 | c.598G>T p.A200S | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT tolerated (1); PolyPhen benign (0.219); catalogued as COSV99357698; called by muse, mutect2, varscan2
- BICC1 | c.787G>A p.A263T | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.038); catalogued as COSV99570521; called by muse, mutect2, varscan2
- BRINP3 | c.1133G>T p.S378I | Missense Mutation (SNP) | VAF 45/92 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV100818758; called by muse, mutect2, varscan2
- BSN | c.11027G>T p.R3676L | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs373281408, COSV99608483; called by muse, mutect2, varscan2
- COL4A4 | c.975G>T p.K325N | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM014171, COSV100306850; called by muse, mutect2, varscan2
- DHX33 | c.1303C>T p.Q435* | Nonsense Mutation (SNP) | VAF 5/52 reads (10%) | catalogued as COSV99834356; called by muse, mutect2, varscan2
- DMD | c.7244G>A p.R2415H | Missense Mutation (SNP) | VAF 24/37 reads (65%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs373749120, COSV58899961; ClinVar: likely benign / benign; called by muse, mutect2, varscan2
- DNAH17 | c.7513T>A p.S2505T | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.777); catalogued as COSV101102331; called by muse, mutect2, varscan2
- DOLK | c.620A>C p.Q207P | Missense Mutation (SNP) | VAF 41/78 reads (53%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.943); catalogued as COSV100455079; called by muse, mutect2, varscan2
- DPYSL5 | c.129G>C p.M43I | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV56511352, COSV99982386; called by muse, mutect2, varscan2
- EID2 | c.418C>T p.L140F | Missense Mutation (SNP) | VAF 24/136 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs754154805, COSV101180485; called by muse, mutect2, varscan2
- FMN2 | c.4950A>T p.K1650N | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100145079; called by muse, mutect2
- GABRA2 | c.220G>A p.V74M | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); catalogued as COSV62912472; called by muse, mutect2, varscan2
- GDA | c.593T>A p.M198K | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.589); catalogued as COSV99429241; called by muse, mutect2, varscan2
- H4C5 | c.13G>A p.G5S | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV100747969, COSV63486720; called by muse, mutect2, varscan2
- HDAC9 | c.2889T>G p.D963E | Missense Mutation (SNP) | VAF 37/139 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as COSV101286772; called by muse, mutect2, varscan2
- HELB | c.2465A>G p.N822S | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0.029); catalogued as COSV99921914; called by muse, mutect2, varscan2
- HERC2 | c.11035G>A p.E3679K | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.515); catalogued as rs760983057, COSV99873786; called by muse, mutect2, varscan2
- INTS1 | c.3424_3429+20del p.X1142_splice | Splice Site (DEL) | VAF 22/88 reads (25%) | catalogued as rs774959930; called by muse*, mutect2
- KLHL24 | c.721G>A p.V241I | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.274); catalogued as rs758623370, COSV54424631; called by muse, mutect2, varscan2
- LRIG2 | c.2712T>G p.D904E | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.935); catalogued as COSV100743353; called by muse, mutect2, varscan2
- LRRTM3 | c.41T>C p.V14A | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (0.42); PolyPhen benign (0.017); catalogued as COSV100791665; called by muse, varscan2
- MCM6 | c.1672A>G p.R558G | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0.309); catalogued as rs1179477512, COSV99919060; called by muse, mutect2, varscan2
- MROH5 | c.3598C>T p.R1200W | Missense Mutation (SNP) | VAF 58/77 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs746532851, COSV100267222; called by muse, mutect2, varscan2
- MTA2 | c.1349A>G p.N450S | Missense Mutation (SNP) | VAF 71/145 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as COSV99545304; called by muse, mutect2, varscan2
- MTRR | c.349C>T p.R117W (on ENST00000264668; = p.R90W on NM_002454.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.061); catalogued as rs773984668, COSV52945478; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NEDD4L | c.740G>A p.R247Q | Missense Mutation (SNP) | VAF 23/38 reads (61%) | SIFT tolerated (0.19); PolyPhen benign (0.103); catalogued as rs747072217, COSV99894842; called by muse, mutect2, varscan2
- NFATC4 | c.1429C>T p.R477W | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs763157014, COSV99145835; called by muse, mutect2, varscan2
- NPY5R | c.277T>C p.F93L | Missense Mutation (SNP) | VAF 69/225 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.19); catalogued as COSV100642774; called by muse, mutect2, varscan2
- OR4C16 | c.388T>A p.Y130N | Missense Mutation (SNP) | VAF 67/167 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as COSV100114062; called by muse, mutect2, varscan2
- OR5L2 | c.156C>A p.S52R | Missense Mutation (SNP) | VAF 107/346 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as COSV101004319; called by muse, mutect2, varscan2
- PCDH10 | c.364T>C p.F122L | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV99993573; called by muse, mutect2, varscan2
- PCDH11X | c.3802C>A p.H1268N | Missense Mutation (SNP) | VAF 77/161 reads (48%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV100011727; called by muse, mutect2, varscan2
- POLD1 | c.1165G>C p.D389H | Missense Mutation (SNP) | VAF 22/176 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101486862; called by muse, mutect2, varscan2
- REG3G | c.266C>T p.S89F | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV99709430; called by muse, mutect2, varscan2
- RNF14 | c.958C>G p.Q320E | Missense Mutation (SNP) | VAF 60/93 reads (65%) | SIFT tolerated (0.1); PolyPhen benign (0.036); catalogued as COSV100641220; called by muse, mutect2, varscan2
- SPTA1 | c.5708T>C p.I1903T | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.561); catalogued as COSV100934955; called by muse, mutect2, varscan2
- SRRT | c.1807G>A p.E603K | Missense Mutation (SNP) | VAF 34/247 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as COSV99574114; called by muse, mutect2, varscan2
- TBC1D20 | c.703G>A p.V235I | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.54); PolyPhen benign (0.107); catalogued as rs1317605747, COSV100830542; called by muse, mutect2, varscan2
- TIAM2 | c.2141C>A p.A714E | Missense Mutation (SNP) | VAF 85/245 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100019098; called by muse, mutect2, varscan2
- TLE6 | c.449A>G p.K150R (on ENST00000246112 / NM_001143986.2; = p.K27R on NM_024760.3) | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.52); catalogued as COSV99858211; called by muse, mutect2, varscan2
- TMEM132D | c.167C>T p.A56V | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs372764040; called by muse, mutect2, varscan2
- TRPS1 | c.2762G>C p.G921A (on ENST00000220888 / NM_001330599.2; = p.G934A on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 148/180 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM083791, COSV99630902; called by muse, mutect2, varscan2
- ZBP1 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.87); PolyPhen benign (0.101); catalogued as rs1372897343, COSV100473477; called by muse, mutect2, varscan2
- ZNF24 | c.614A>G p.E205G | Missense Mutation (SNP) | VAF 65/111 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as rs1349174458, COSV99734277; called by muse, mutect2, varscan2
- CHD5 | c.2077_2079del p.I693del | In Frame Del (DEL) | VAF 14/81 reads (17%) | called by mutect2, pindel, varscan2
- FOLR1 | c.36_38del p.L13del | In Frame Del (DEL) | VAF 33/119 reads (28%) | called by mutect2, pindel, varscan2
- PPL | c.1232dup p.E413Gfs*46 | Frame Shift Ins (INS) | VAF 12/50 reads (24%) | called by mutect2, pindel, varscan2
- SPOCD1 | c.2129_2145+1del p.X710_splice | Splice Site (DEL) | VAF 17/106 reads (16%) | called by mutect2, pindel
- ZNF420 | c.1887dup p.L630Sfs*11 | Frame Shift Ins (INS) | VAF 32/76 reads (42%) | called by mutect2, pindel, varscan2
- AATK | c.96C>T p.L32= | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as rs1158339482, COSV58686489; called by muse, mutect2, varscan2
- ASTN1 | c.1065C>T p.N355= | Silent (SNP) | VAF 18/34 reads (53%) | catalogued as rs61758728; called by muse, mutect2, varscan2
- CHRDL1 | c.543A>G p.E181= (on ENST00000372045; = p.E187= on NM_145234.4) | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as COSV99488143; called by muse, mutect2, varscan2
- CUX1 | c.2202C>T p.S734= | Silent (SNP) | VAF 25/370 reads (7%) | catalogued as rs150235372, COSV52919421; called by muse, mutect2
- DLGAP3 | c.1140C>T p.T380= | Silent (SNP) | VAF 37/169 reads (22%) | catalogued as rs149715442, COSV52394832; called by muse, mutect2, varscan2
- DYNC2H1 | c.780A>T p.G260= | Silent (SNP) | VAF 13/401 reads (3%) | catalogued as COSV100518576; called by muse, mutect2
- EPHX1 | c.804C>T p.F268= | Silent (SNP) | VAF 43/205 reads (21%) | catalogued as rs369274884; called by muse, mutect2, varscan2
- HCRTR1 | c.898C>T p.L300= | Silent (SNP) | VAF 8/60 reads (13%) | catalogued as rs1345639549, COSV65486900; called by muse, mutect2, varscan2
- IL1R2 | c.579C>T p.L193= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as rs749459091, COSV100208107, COSV60207007; called by muse, mutect2, varscan2
- IL9R | c.321A>G p.P107= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as COSV99729763; called by muse, mutect2, varscan2
- LCT | c.3135C>T p.Y1045= | Silent (SNP) | VAF 28/86 reads (33%) | catalogued as rs754582267, COSV51555493; called by muse, mutect2, varscan2
- LRRC66 | c.1134G>A p.A378= | Silent (SNP) | VAF 33/95 reads (35%) | catalogued as rs373547671, COSV100602960; called by muse, mutect2, varscan2
- REV1 | c.711G>A p.K237= | Silent (SNP) | VAF 4/37 reads (11%) | catalogued as rs1315943320, COSV51481474, COSV99300942; called by muse, mutect2, varscan2
- SIRPG | c.375G>A p.G125= | Silent (SNP) | VAF 58/142 reads (41%) | catalogued as rs1263661521, COSV99403768; called by muse, mutect2, varscan2
- TNFSF4 | c.342C>T p.N114= | Silent (SNP) | VAF 13/62 reads (21%) | catalogued as COSV56056065; called by muse, mutect2, varscan2
- TRAV20 | c.33C>A p.V11= | Silent (SNP) | VAF 56/99 reads (57%) | called by muse, mutect2, varscan2
- TUBAL3 | c.1170G>A p.A390= | Silent (SNP) | VAF 33/82 reads (40%) | catalogued as rs782269668, COSV66814534; called by muse, mutect2, varscan2
- NACA | c.71-2694T>A | Intron (SNP) | VAF 10/35 reads (29%) | catalogued as COSV100771331; called by muse, mutect2, varscan2
- TK2 | c.31+167G>A | Intron (SNP) | VAF 9/29 reads (31%) | catalogued as rs1477082921; called by muse, mutect2
